Somatic mutation profile of tumor specimen TARGET-10-PATBYK-09A (aliquot TARGET-10-PATBYK-09A-01D) from TARGET case TARGET-10-PATBYK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.4 years (6,000 days).
Specimen TARGET-10-PATBYK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 995ebf53-ebbc-4c54-a5fd-85c8a6825dba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATBYK-10A (Blood Derived Normal), aliquot TARGET-10-PATBYK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b142ae9-4feb-4cf1-bbb5-1f1253c40288

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 2, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CR2 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as COSV65508854; called by muse, mutect2, varscan2
- DHRS4L2 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs762000184, COSV58729198; called by muse, varscan2
- FLNA | c.3392C>T p.P1131L | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV61048241; called by muse, mutect2, varscan2
- HTATSF1 | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 25/63 reads (40%) | catalogued as COSV54480185, COSV54480217; called by muse, mutect2, varscan2
- LLGL2 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs749734318, COSV51341705; called by muse, mutect2, varscan2
- PPEF2 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs1429833805, COSV54420586; called by muse, mutect2, varscan2
- PTPRS | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV53630357; called by muse, mutect2, varscan2
- TST | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.16); catalogued as COSV50765623; called by muse, varscan2
- RALGDS | c.2198G>A p.G733D | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.446); called by muse, mutect2
- ALDH3A1 | c.1167C>T p.N389= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as rs1279111902; called by muse, mutect2, varscan2
- INSR | c.2391T>C p.P797= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- ALDH1L1 | c.2182-64G>A | Intron (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1124-158C>T | Intron (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
